Gene-level copy-number profile of tumor specimen TCGA-27-2518-01A from TCGA case TCGA-27-2518, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.4 years (19,130 days).
Specimen TCGA-27-2518-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.385df857-e594-4d8a-8d15-dfa23aab9dd6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-27-2518-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6a3928f0-19e5-4c7d-816c-c99f31d118f8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 4,942; copy number 2: 48,569; copy number 3: 6,258; copy number 4: 6; copy number 5: 7; copy number 16: 6; copy number 30: 17; copy number 41: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-27-2518-01A-01D-0784-01): tumor purity 0.66, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,260,442–181,835,108, 6 genes: LINC02500, AC093840.1, AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 38 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:204,377,850–204,435,846, 1 gene, copy number 16 (within-gene range 2–16): AL606489.1.
- chr1:204,403,381–204,562,521, 5 genes, copy number 16: PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74.
- chr7:28,953,358–29,195,451, 7 genes, copy number 5 (within-gene range 3–5): TRIL, AC005013.1, AC005162.2, AC005162.1, CPVL, CPVL-AS1, AC005232.1.
- chr7:54,752,250–55,260,256, 8 genes, copy number 41: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr12:57,693,955–57,818,704, 17 genes, copy number 30: OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4.

Autosomal genes at a single copy (total copy number 1): 2,561. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
